Surgical pathology report (de-identified scan), TCGA case TCGA-AN-A0AL, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Cureline, specimen TCGA-AN-A0AL-01A (Primary Tumor).

TSS Patient ID:

Case #: DOB ; Sex: **Female** Ethnicity (Race):

Cancer Sample

Diagnosis: **Breast Cancer** Histological description: **Infiltrative ductal carcinoma**

Date of Procurement:) Anatomic Site: **Left Breast** Tumor location: **Primary**

Tissue Specification: **Tumor** Specimen Matrix: **Tissue** Specimen Format: **OCT**

Container: **block** Type of Procurement: **surgery** Grade: **2**

T Stage: **4** N Stage: **0** M Stage: **0** Treatment: **none**

Treatment Details: **n/a**

Normal Sample

Anatomic Site: **Blood** Sample Type: **Normal** Type of Procurement: **blood draw**

Matrix: **Blood** Specimen Format: **frozen** Container: **tube**

Date of Procurement:

100-0-3

carcinoma, infiltrating duct, NOS 8500/3

site: breast, NOS 050.9

*hw
10/21/11*

Source: NCI Genomic Data Commons file d8961eb0-f5ca-4ee3-9c52-dc7e9a41f8e8 (TCGA-AN-A0AL.20F4DBD9-02FA-4FFD-AEF5-234910D31263.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).